Somatic mutation profile of tumor specimen TCGA-B6-A0IE-01A (aliquot TCGA-B6-A0IE-01A-11W-A050-09) from TCGA case TCGA-B6-A0IE, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 38.3 years (13,982 days).
Specimen TCGA-B6-A0IE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ac8519d-3f94-42ac-9437-e6d80e2a5865.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0IE-10A (Blood Derived Normal), aliquot TCGA-B6-A0IE-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/457a7fe9-e6d6-42fb-a9a1-2b5f067448a7

The open-access MAF lists 31 somatic variants for this specimen: 26 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 4, Nonsense Mutation 3, Intron 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 29/139 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.919+1G>A p.X307_splice | Splice Site (SNP) | VAF 139/298 reads (47%) | hotspot (GDC flag); catalogued as rs1131691039, CD920913, CS107068, CS120864, COSV52683145, COSV52775982, COSV52814989; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.1306T>A p.F436I | Missense Mutation (SNP) | VAF 25/285 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV99287076; called by muse, mutect2
- ABRA | c.230G>T p.S77I | Missense Mutation (SNP) | VAF 66/402 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV61733768; called by muse, mutect2, varscan2
- ADAMTS12 | c.3634C>T p.P1212S | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV61281761; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2644G>A p.V882M | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs747377051, COSV65901039; called by muse, mutect2, varscan2
- APOL5 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as rs769730762, COSV50768799; called by muse, mutect2, varscan2
- BRINP1 | c.1601G>A p.R534H | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs763444329, COSV56307462, COSV99775837; called by muse, mutect2, varscan2
- GJD3 | c.346G>T p.G116* | Nonsense Mutation (SNP) | VAF 5/8 reads (63%) | catalogued as rs748596113, COSV61606110; called by muse, varscan2
- GPR1 | c.136T>G p.C46G | Missense Mutation (SNP) | VAF 43/214 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV67977661; called by muse, mutect2, varscan2
- GUCY2D | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as rs776845104, COSV54696293; called by mutect2, varscan2
- HPS3 | c.2464C>T p.R822* | Nonsense Mutation (SNP) | VAF 35/123 reads (28%) | catalogued as rs369855073; called by muse, mutect2, varscan2
- IL1RN | c.292G>T p.G98C (on ENST00000409930 / NM_173842.3; = p.G80C on NM_000577.5) | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52082194; called by muse, mutect2, varscan2
- MUC4 | c.13291G>A p.E4431K (on ENST00000463781 / NM_018406.7; = p.E195K on NM_004532.6) | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs1462978621, COSV57805454; called by muse, mutect2, varscan2
- MYO5B | c.5497T>G p.S1833A | Missense Mutation (SNP) | VAF 77/273 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as COSV53232729; called by muse, mutect2, varscan2
- NLK | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1414954380, COSV63490782; called by muse, mutect2, varscan2
- PSG9 | c.764A>C p.K255T | Missense Mutation (SNP) | VAF 22/494 reads (4%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.98); catalogued as COSV99392627; called by muse, mutect2
- PSMD5 | c.933G>A p.M311I | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV99270951; called by muse, mutect2
- RIC8A | c.1243A>G p.N415D (on ENST00000526104 / NM_001286134.1; = p.N421D on NM_021932.5) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV57344436; called by muse, mutect2, varscan2
- ROR1 | c.1624G>A p.V542I | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.544); catalogued as rs139362871, COSV64293813; called by muse, mutect2, varscan2
- RTTN | c.840C>T p.H280= | Splice Region (SNP) | VAF 44/177 reads (25%) | catalogued as rs192562671, COSV55352046; called by muse, mutect2, varscan2
- TBC1D2B | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV56046621; called by muse, mutect2, varscan2
- ZNF3 | c.116C>G p.A39G | Missense Mutation (SNP) | VAF 115/380 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as COSV52795509, COSV52796635; called by muse, mutect2, varscan2
- ZNF439 | c.1138A>T p.K380* | Nonsense Mutation (SNP) | VAF 50/150 reads (33%) | catalogued as rs1329778692, COSV58311320; called by muse, mutect2, varscan2
- CCDC144A | c.1633C>A p.L545I | Missense Mutation (SNP) | VAF 18/641 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- PRAMEF14 | c.1024G>C p.A342P | Missense Mutation (SNP) | VAF 171/623 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- AREL1 | c.1320G>A p.Q440= | Silent (SNP) | VAF 7/138 reads (5%) | catalogued as COSV100707660; called by muse, mutect2
- LTF | c.711G>A p.L237= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV51612535; called by muse, mutect2, varscan2
- PRICKLE1 | c.2409T>A p.S803= | Silent (SNP) | VAF 175/526 reads (33%) | catalogued as COSV58210775; called by muse, mutect2, varscan2
- VPS39 | c.1539G>A p.G513= (on ENST00000348544 / NM_001301138.2; = p.G502= on NM_015289.5) | Silent (SNP) | VAF 52/159 reads (33%) | catalogued as COSV58793839; called by muse, mutect2, varscan2
- KIF2A | c.1647-1221G>C | Intron (SNP) | VAF 99/211 reads (47%) | catalogued as COSV66946901; called by muse, mutect2, varscan2
